Gene-level copy-number profile of tumor specimen TCGA-L5-A43I-01A from TCGA case TCGA-L5-A43I, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 77.7 years (28,367 days).
Specimen TCGA-L5-A43I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.3ba727bb-b1da-4b39-bcb7-0062a300d63b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A43I-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50c208ba-ea31-40c4-afdb-1afdbc8b2e68

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 2,241; copy number 2: 9,437; copy number 3: 23,966; copy number 4: 12,962; copy number 5: 8,060; copy number 6: 1,882; copy number 7: 368; copy number 8: 342; copy number 9: 155; copy number 10: 130; copy number 11: 20; copy number 12: 6; copy number 13: 102; copy number 14: 82; copy number 18: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A43I-01A-11D-A246-01): tumor purity 0.67, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:11,658,178–11,827,409, 8 genes: NTSR2, CDK8P1, AC106875.2, LPIN1, AC106875.1, AC012456.1, AC012456.2, MIR548S.
- chr2:11,836,933–11,836,986, 1 gene: MIR4262.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr4:186,286,094–187,309,682, 16 genes (within-gene range 0–1): F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2, AC108046.1, LINC02374, AC097652.1.
- chr7:31,337,465–31,340,726, 1 gene: NEUROD6.
- chr13:91,485,793–91,486,870, 1 gene: AL356118.1.
- chr18:39,622,123–39,678,622, 5 genes: MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,223 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,363,281–112,671,616, 10 genes, copy number 9–10: TXNP3, AL591521.1, CTTNBP2NL, MIR4256, WNT2B, AL354760.1, ST7L, CAPZA1, MRPL53P1, RNU7-70P.
- chr1:114,089,291–116,571,039, 55 genes, copy number 9–18 (within-gene range 3–18): SYT6, AL121999.1, MRPL57P1, AL035410.2, TRIM33, AL035410.1, EIF2S2P5, Y_RNA, PKMP1, BCAS2, DENND2C, AMPD1, RN7SL432P, NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1, CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779, U3, AL355538.1, ATP1A1, ATP1A1-AS1, RNU6-817P, LINC01762, AL136376.1, Y_RNA, AL390066.1, AL390066.2, CD58, NAP1L4P1.
- chr2:55,172,547–63,087,322, 128 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).
- chr2:63,108,118–63,119,542, 2 genes, copy number 10: RPL27P5, DBIL5P2.
- chr7:54,185,071–55,433,742, 21 genes, copy number 7–10 (within-gene range 5–10): AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr7:102,813,230–103,074,843, 1 gene, copy number 8 (within-gene range 2–8): FBXL13.
- chr7:102,913,000–103,989,658, 21 genes, copy number 8: LRRC17, NFE4, AC073127.1, ARMC10, CRYZP1, NAPEPLD, AC007683.1, RPL23AP95, AC007683.3, DPY19L2P2, S100A11P1, PMPCB, DNAJC2, PSMC2, RPS29P16, SLC26A5, Y_RNA, Y_RNA, AC005064.1, RELN, RN7SKP86.
- chr8:9,984,004–12,756,073, 119 genes, copy number 10–13 (broad region; genes not listed).
- chr8:42,128,774–42,555,195, 15 genes, copy number 10: AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr8:91,909,738–91,917,918, 2 genes, copy number 13: PRR13P7, MRPS16P1.
- chr8:99,960,936–103,298,772, 96 genes, copy number 9–14 (within-gene range 6–14) (broad region; genes not listed).
- chr9:35,406,755–37,592,604, 88 genes, copy number 8–14 (broad region; genes not listed).
- chr9:37,636,688–37,778,972, 4 genes, copy number 14: RAB1C, FRMPD1, RN7SKP171, TRMT10B.
- chr11:68,030,617–70,436,584, 69 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 7: AP001271.1.
- chr13:23,134,174–24,597,676, 37 genes, copy number 9 (within-gene range 4–9): HMGA1P6, RNY3P4, LINC00362, SGCG, RNU6-58P, TATDN2P3, SDAD1P4, SACS, RPLP1P13, SACS-AS1, LINC00327, LINC00352, TNFRSF19, MIPEP, MTCO3P2, PCOTH, C1QTNF9B, ANKRD20A19P, AL445985.2, AL359736.1, SPATA13, AL445985.1, IPO7P2, MIR2276, SPATA13-AS1, C1QTNF9, C1QTNF9-AS1, AL359736.2, NUS1P3, LINC00566, CYCSP33, TPTE2P6, PARP4, AL359538.4, AL359538.3, PSPC1P2, AL359538.1.
- chr13:39,655,627–57,204,799, 322 genes, copy number 8–10 (broad region; genes not listed).
- chr14:50,050,368–50,116,600, 5 genes, copy number 7: PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT.
- chr17:26,981,694–29,551,903, 145 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr18:20,946,906–24,453,531, 82 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
